Gene-level copy-number profile of tumor specimen HTMCP-03-06-02099-01A from CGCI case HTMCP-03-06-02099, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02099-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e37a5af1-de1e-4a02-9200-0921fa7ad11e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02099-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/c7076f8a-5515-409e-a7db-616d46021bf3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 1,250; copy number 2: 9,791; copy number 3: 27,333; copy number 4: 12,630; copy number 5: 982; copy number 6: 647; copy number 7: 4,260; copy number 8: 1,391; copy number 9: 18; copy number 15: 7; copy number 18: 1; copy number 21: 7; copy number 24: 9; copy number 34: 2; copy number 35: 46.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,521,803–75,522,012, 1 gene: SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–2): RPS3AP15.
- chr4:9,153,296–9,212,249, 4 genes: FAM86KP, ALG1L14P, FAM90A26, USP17L10.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.
- chr8:8,059,572–8,226,614, 8 genes: AC105233.4, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17, ENPP7P1, FAM85B, AC068020.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,738 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–248,937,043, 2,524 genes, copy number 7–8 (broad region; genes not listed).
- chr3:96,814,581–163,361,563, 1,102 genes, copy number 7 (broad region; genes not listed).
- chr3:167,864,773–198,123,232, 591 genes, copy number 7 (broad region; genes not listed).
- chr7:38,239,580–38,335,514, 15 genes, copy number 8: TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr9:65,189,995–65,285,209, 5 genes, copy number 7: BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5.
- chr11:83,072,052–89,826,922, 127 genes, copy number 8–9 (broad region; genes not listed).
- chr11:90,118,391–91,015,299, 13 genes, copy number 7: AP000648.1, AP000648.3, NAALAD2, AP000648.4, CHORDC1, AP002364.1, DISC1FP1, TUBAP2, MIR4490, AP002782.1, MIR1261, AP001002.3, AP001002.1.
- chr11:91,794,319–103,479,863, 184 genes, copy number 7–35 (broad region; genes not listed).
- chr11:110,355,130–110,464,884, 2 genes, copy number 34: LINC02732, FDX1.
- chr14:22,197,446–22,482,959, 1 gene, copy number 8 (within-gene range 6–8): AC244502.1.
- chr14:22,226,746–22,490,553, 33 genes, copy number 8: TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48.
- chr14:22,547,506–22,552,156, 1 gene, copy number 8: TRAC.
- chr19:27,638,483–27,646,483, 2 genes, copy number 8: ERVK-28, AC112702.1.
- chr19:41,521,043–58,605,223, 1,138 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,250. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
